Somatic mutation profile of tumor specimen TCGA-DJ-A2PU-01A (aliquot TCGA-DJ-A2PU-01A-12D-A19J-08) from TCGA case TCGA-DJ-A2PU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 52.0 years (18,998 days).
Specimen TCGA-DJ-A2PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d0da445-c7e0-4c13-87a9-7c22d0f8de01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PU-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PU-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24caaa6b-c5c3-46fb-a6d0-fe2e1a589a97

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DTYMK | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59871524; called by muse, varscan2
- ENPEP | c.1431A>G p.I477M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54452933; called by muse, mutect2, varscan2
- GLOD4 | c.433C>T p.R145C (on ENST00000301328 / NM_001366247.1; = p.R130C on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs529543488, COSV56754068; called by muse, mutect2, varscan2
- SPTBN1 | c.2457C>A p.D819E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV61689877; called by muse, mutect2, varscan2
- UBE2O | c.2637G>A p.M879I | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV60064664; called by muse, mutect2
- PLAC1 | c.528C>A p.V176= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV63656294; called by muse, mutect2
